Somatic mutation profile of tumor specimen MMRF_1759_1_BM_CD138pos (aliquot MMRF_1759_1_BM_CD138pos_T1_KBS5U_L05549) from MMRF case MMRF_1759, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.1 years (27,809 days).
Specimen MMRF_1759_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79b91bfe-320e-4e82-8ecb-a5af522843a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1759_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1759_1_PB_WBC_C3_KBS5U_L05571; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e8433b6-68cb-47a2-be83-25854edf0430

The open-access MAF lists 86 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 23, Silent 12, Intron 6, Nonsense Mutation 3, 5'UTR 3, Frame Shift Del 2, 3'Flank 2, 5'Flank 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 49/104 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACTR3B | c.45G>A p.G15= | Splice Region (SNP) | VAF 22/90 reads (24%) | catalogued as rs746445736; called by muse, mutect2, varscan2
- B2M | c.292T>G p.Y98D | Missense Mutation (SNP) | VAF 96/281 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62565095, COSV62565473; called by muse, varscan2
- DNMT3A | c.2205C>G p.Y735* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs765439043; called by muse, mutect2, varscan2
- FAT3 | c.12661G>A p.V4221I | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749339528, COSV53082658; called by muse, mutect2, varscan2
- FRMD4B | c.1610A>C p.D537A | Missense Mutation (SNP) | VAF 104/369 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs773085991; called by muse, mutect2, varscan2
- GPSM3 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV66683788; called by muse, mutect2, varscan2
- GRIK3 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1423778857, COSV66143156; called by muse, mutect2, varscan2
- IGLV2-14 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.076); catalogued as rs373891287; called by muse, varscan2
- IGLV3-25 | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs61997240; called by muse, varscan2
- IGLV3-25 | c.250A>G p.S84G | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1433743522; called by muse, varscan2
- IRAK1 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs782207964; called by muse, mutect2, varscan2
- IRS2 | c.2104G>A p.V702M | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs1178312245; called by muse, mutect2, varscan2
- LLGL1 | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 60/124 reads (48%) | catalogued as rs537626619, COSV57496713; called by muse, mutect2, varscan2
- MPPED2 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100813153; called by muse, mutect2, varscan2
- OLFML2A | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 78/243 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753469559; called by muse, mutect2, varscan2
- OR3A3 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.298); catalogued as rs775488301, COSV52167304; called by muse, mutect2, varscan2
- PARP12 | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972952229; called by muse, mutect2, varscan2
- PIEZO2 | c.4073C>T p.T1358M | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777349822, COSV100123409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCH2 | c.4126C>T p.R1376W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs550023756; called by muse, mutect2, varscan2
- SEMA3F | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs757018373; called by muse, mutect2, varscan2
- SLC17A6 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781200170; called by muse, mutect2, varscan2
- ST6GAL2 | c.773G>C p.R258P | Missense Mutation (SNP) | VAF 17/43 reads (40%) | PolyPhen possibly damaging (0.841); catalogued as COSV64527534; called by muse, mutect2, varscan2
- ADAMTS7 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- APBA2 | c.1328C>A p.A443E | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- APOB | c.13633A>G p.T4545A | Missense Mutation (SNP) | VAF 203/444 reads (46%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPP9 | c.2489A>G p.Y830C (on ENST00000598800; = p.Y859C on NM_139159.5) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTA3 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MTUS1 | c.42G>T p.L14F | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- NELL2 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 95/218 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- OR52A1 | c.1_2del p.M1? | Frame Shift Del (DEL) | VAF 200/723 reads (28%) | called by mutect2, pindel, varscan2
- RHOV | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SHROOM3 | c.2095A>C p.T699P | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- SLC11A2 | c.1126A>T p.K376* (on ENST00000394904 / NM_001379455.1; = p.K347* on NM_000617.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/201 reads (8%) | called by muse, mutect2
- SP100 | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TMPRSS11D | c.190_193del p.Q64* | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- TNFRSF19 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF638 | c.3596C>G p.A1199G | Missense Mutation (SNP) | VAF 113/225 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ANO2 | c.2160G>A p.S720= (on ENST00000356134 / NM_001278597.3; = p.S724= on NM_001278596.3) | Silent (SNP) | VAF 64/132 reads (48%) | catalogued as rs368141631; called by muse, mutect2, varscan2
- DISP3 | c.4017C>T p.A1339= | Silent (SNP) | VAF 68/118 reads (58%) | called by muse, mutect2, varscan2
- ELFN2 | c.1491C>T p.A497= | Silent (SNP) | VAF 74/152 reads (49%) | catalogued as rs1569132110; called by muse, mutect2
- ERMAP | c.168C>T p.P56= | Silent (SNP) | VAF 59/138 reads (43%) | catalogued as rs758771948; called by muse, mutect2, varscan2
- IGHV3-43 | c.285A>G p.K95= | Silent (SNP) | VAF 66/140 reads (47%) | catalogued as rs1357905017; called by muse, mutect2
- LDLRAD4 | c.174C>T p.I58= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- MID1 | c.9A>G p.T3= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV58191568; called by muse, mutect2, varscan2
- NALCN | c.4551C>T p.Y1517= | Silent (SNP) | VAF 49/88 reads (56%) | catalogued as rs748173874, COSV51929902; called by muse, mutect2, varscan2
- PLEKHG6 | c.1026C>T p.A342= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs148707090; called by muse, mutect2, varscan2
- RTEL1 | c.3489T>A p.A1163= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- SMOC1 | c.1095C>T p.H365= | Silent (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- ZXDC | c.606T>G p.G202= | Silent (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- ADORA3 | c.*511C>T | 3'UTR (SNP) | VAF 22/36 reads (61%) | called by muse, mutect2, varscan2
- ANKRD12 | c.*407T>A | 3'UTR (SNP) | VAF 55/112 reads (49%) | called by muse, mutect2, varscan2
- APLP2 | c.*1078C>T | 3'UTR (SNP) | VAF 48/204 reads (24%) | catalogued as rs1253628871, COSV99599347; called by muse, mutect2, varscan2
- C1QTNF2 | c.*503C>T | 3'UTR (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- C20orf194 | c.*2219C>T | 3'UTR (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- CARF | c.832+869C>T | Intron (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- CBFB | c.*680A>C | 3'UTR (SNP) | VAF 22/45 reads (49%) | catalogued as rs1050419120; called by muse, varscan2
- CCL22 | c.*1778C>T | 3'UTR (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- DNAJB4 | c.*633T>C | 3'UTR (SNP) | VAF 57/109 reads (52%) | called by muse, mutect2, varscan2
- EPPIN-WFDC6 | c.522+429T>C | Intron (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- FGA | c.*478T>G | 3'UTR (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- FLI1 | c.*526A>C | 3'UTR (SNP) | VAF 54/90 reads (60%) | called by muse, mutect2, varscan2
- GALNT9 | c.*719A>G | 3'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- HYAL1 | c.-313T>A | 5'UTR (SNP) | VAF 27/327 reads (8%) | called by muse, mutect2
- ITSN1 | c.*3813T>C | 3'UTR (SNP) | VAF 15/65 reads (23%) | catalogued as rs1009248498; called by muse, mutect2
- LCOR | c.*1722G>C | 3'UTR (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- LETM1 | c.*215T>G | 3'UTR (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- MAGEB6 | c.*152del | 3'UTR (DEL) | VAF 35/50 reads (70%) | called by mutect2, pindel, varscan2
- MPG | c.-124G>C | 5'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- NOTCH2 | c.751+872A>G | Intron (SNP) | VAF 115/217 reads (53%) | called by muse, mutect2, varscan2
- OPTN | chr10:13137764 C>T | 3'Flank (SNP) | VAF 43/90 reads (48%) | catalogued as rs915548286; called by muse, mutect2, varscan2
- OR11K2P | n.410C>T | RNA (SNP) | VAF 35/177 reads (20%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*3938A>G | 3'UTR (SNP) | VAF 47/101 reads (47%) | called by muse, mutect2, varscan2
- PTCD3 | c.*2302T>G | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- RGS5 | c.*2564del | 3'UTR (DEL) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- RORA | c.*5424A>G | 3'UTR (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2
- RPL31 | c.1-182C>T | Intron (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- RPP25 | c.-108C>T | 5'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- SEMA4D | c.*605C>T | 3'UTR (SNP) | VAF 63/196 reads (32%) | catalogued as rs974862282; called by muse, mutect2, varscan2
- SLC25A43 | c.691-99C>G | Intron (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2
- SLC5A1 | c.*2416C>A | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- SNORD116-17 | chr15:25088539 A>T | 3'Flank (SNP) | VAF 68/173 reads (39%) | called by muse, mutect2, varscan2
- SPA17 | c.-27-312G>A | Intron (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- SPTAN1 | c.*106A>G | 3'UTR (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- TMEM150C | chr4:82562316 G>T | 5'Flank (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- TRIM40 | c.*294G>T | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
